Somatic mutation profile of tumor specimen 0DECXG from CCDI case PBBPVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.3 years (3,746 days).
Specimen 0DECXG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f0e0806-212a-44e9-99a9-4af284c5c581.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DECX1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaf8969f-80c6-4b83-995e-1d46f664d143

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 9.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARHSP1 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 203/609 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs762364897, COSV60683852; called by muse, varscan2
- CTNNA3 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 240/807 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65566199; called by muse, varscan2
- NRG1 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 100/940 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs372445359, COSV55160683, COSV99828919; called by muse, varscan2
- OLFM4 | c.238C>G p.R80G | Missense Mutation (SNP) | VAF 86/778 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV54577130; called by muse, varscan2
- TNXB | c.9413C>T p.P3138L (on ENST00000647633; = p.P2891L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 163/600 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as rs749347431; called by muse, varscan2
- BDP1 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 58/585 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- ENO4 | c.571C>T p.P191S (on ENST00000622726; = p.P190S on NM_001242699.2) | Missense Mutation (SNP) | VAF 118/1084 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.027); called by muse, varscan2
- OTOG | c.5383G>A p.A1795T | Missense Mutation (SNP) | VAF 62/392 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.022); called by muse, varscan2
- SEMA6D | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 141/800 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
